Somatic mutation profile of tumor specimen TCGA-L5-A8NT-01A (aliquot TCGA-L5-A8NT-01A-11D-A37C-09) from TCGA case TCGA-L5-A8NT, project TCGA-ESCA (Esophageal Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lower third of esophagus; AJCC pathologic stage: Stage IIB; Tumor grade: GX; Age at diagnosis: 69.2 years (25,259 days).
Specimen TCGA-L5-A8NT-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b6f20500-f87e-4731-8ba1-b6bf703c46a8.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-L5-A8NT-11A (Solid Tissue Normal), aliquot TCGA-L5-A8NT-11A-11D-A37F-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/be2ba418-b608-4efe-8507-fc1c9ef41549

The open-access MAF lists 105 somatic variants for this specimen: 80 protein-altering or splice-affecting, 25 silent.
By variant classification: Missense Mutation 68, Silent 25, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 3, Splice Site 1, Nonstop Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 20/68 reads (29%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.404G>T p.C135F | Missense Mutation (SNP) | VAF 21/37 reads (57%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs587781991, COSV52675774, COSV52680475, COSV52702460, COSV53452020; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS16 | c.2546C>A p.P849Q | Missense Mutation (SNP) | VAF 72/99 reads (73%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs755952454, COSV57001956, COSV57007028; called by muse, mutect2, varscan2
- ANGPTL2 | c.1376G>A p.R459Q | Missense Mutation (SNP) | VAF 14/65 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs748835465; called by muse, mutect2, varscan2
- AOC3 | c.1367C>T p.A456V | Missense Mutation (SNP) | VAF 30/72 reads (42%) | SIFT tolerated (0.73); PolyPhen benign (0.005); catalogued as rs367848102; called by muse, mutect2, varscan2
- BNC1 | c.791A>C p.Y264S | Missense Mutation (SNP) | VAF 28/62 reads (45%) | SIFT tolerated (0.3); PolyPhen benign (0.006); catalogued as COSV100597562; called by muse, mutect2, varscan2
- CCDC102A | c.674C>T p.P225L | Missense Mutation (SNP) | VAF 15/58 reads (26%) | SIFT tolerated (0.69); PolyPhen benign (0.001); catalogued as rs746101246, COSV50777310, COSV50777339; called by muse, mutect2, varscan2
- CHST11 | c.242G>A p.R81Q | Missense Mutation (SNP) | VAF 14/40 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100359881, COSV57984419; called by muse, mutect2
- DNAH10 | c.6128C>T p.A2043V (on ENST00000409039; = p.A1982V on NM_207437.3) | Missense Mutation (SNP) | VAF 37/107 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs774564007, COSV68989077; called by muse, mutect2, varscan2
- DNAJC24 | c.160G>T p.E54* | Nonsense Mutation (SNP) | VAF 27/88 reads (31%) | catalogued as COSV71938607; called by muse, mutect2, varscan2
- FAM131B | c.385G>A p.V129I | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.127); catalogued as rs897794481, COSV68126225; called by muse, mutect2, varscan2
- FLG | c.7427C>A p.S2476Y | Missense Mutation (SNP) | VAF 78/194 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs780111314, COSV64252088; called by muse, mutect2, varscan2
- GABBR2 | c.493G>A p.D165N | Missense Mutation (SNP) | VAF 17/59 reads (29%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.996); catalogued as rs1449813941, COSV99411110; called by muse, mutect2, varscan2
- GPAT2 | c.1681C>T p.R561W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.891); catalogued as rs749617144; called by muse, mutect2, varscan2
- GPC1 | c.1613C>T p.P538L | Missense Mutation (SNP) | VAF 23/126 reads (18%) | SIFT tolerated (0.47); PolyPhen benign (0.001); catalogued as rs372909320; called by muse, mutect2, varscan2
- GPR32 | c.511G>A p.A171T | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.905); catalogued as rs779158621; called by muse, mutect2, varscan2
- HK2 | c.272G>A p.R91H | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as rs746133519, COSV51880831; called by muse, mutect2, varscan2
- IGSF21 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs774817306, COSV52125830; called by muse, mutect2, varscan2
- KCNB2 | c.139G>T p.E47* | Nonsense Mutation (SNP) | VAF 30/90 reads (33%) | catalogued as COSV73051743; called by muse, mutect2, varscan2
- KCNK4 | c.163G>A p.D55N | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (0.27); PolyPhen benign (0.012); catalogued as COSV57402447; called by muse, mutect2, varscan2
- KLHL24 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 48/135 reads (36%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.487); catalogued as rs547446710, COSV54425693; called by muse, mutect2, varscan2
- LRRC8A | c.613G>A p.V205M | Missense Mutation (SNP) | VAF 7/28 reads (25%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.711); catalogued as rs764489463; called by muse, mutect2, varscan2
- MAGEC1 | c.2002G>C p.E668Q | Missense Mutation (SNP) | VAF 19/55 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.062); catalogued as rs1228342059, COSV53573090; called by muse, mutect2, varscan2
- MAP2K3 | c.455G>A p.R152Q (on ENST00000342679 / NM_145109.3; = p.R123Q on NM_002756.4) | Missense Mutation (SNP) | VAF 32/126 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs148304866; called by muse, mutect2
- MCMDC2 | c.1114C>T p.R372C | Missense Mutation (SNP) | VAF 45/112 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.001); catalogued as rs769985194, COSV58039608; called by muse, mutect2, varscan2
- MX2 | c.505G>A p.G169R | Missense Mutation (SNP) | VAF 18/42 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs199686102, COSV58094951; called by muse, mutect2, varscan2
- NFXL1 | c.1055G>A p.R352K | Missense Mutation (SNP) | VAF 32/56 reads (57%) | SIFT deleterious (0.03); PolyPhen benign (0.005); catalogued as rs1291547522; called by muse, mutect2, varscan2
- NLE1 | c.685C>T p.R229W | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs748512588, COSV100680834, COSV62604297; called by muse, mutect2, varscan2
- NOD2 | c.2122C>T p.R708C | Missense Mutation (SNP) | VAF 35/74 reads (47%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.87); catalogued as rs747241427; called by muse, mutect2, varscan2
- PAX4 | c.520C>T p.R174W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763356440, COSV58389386; called by muse, mutect2, varscan2
- PRAMEF1 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 38/440 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.001); catalogued as rs377131924; called by muse, mutect2
- PRAMEF2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 31/223 reads (14%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs576051310, COSV53574874; called by muse, mutect2, varscan2
- RBM19 | c.2395G>A p.V799M | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as rs1252351010, COSV99926098; called by muse, mutect2, varscan2
- SALL3 | c.1964C>T p.S655L | Missense Mutation (SNP) | VAF 5/10 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); catalogued as rs765362184, COSV73305783; called by muse, mutect2, varscan2
- SEMA6A | c.2737G>A p.G913R | Missense Mutation (SNP) | VAF 24/53 reads (45%) | SIFT tolerated (0.16); PolyPhen benign (0.178); catalogued as rs765850706, COSV56714683; called by muse, mutect2, varscan2
- SNTG2 | c.811G>A p.A271T | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.255); catalogued as COSV100422121; called by muse, mutect2, varscan2
- SOX10 | c.310G>A p.V104I | Missense Mutation (SNP) | VAF 42/155 reads (27%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.956); catalogued as rs752595410; called by muse, mutect2, varscan2
- SOX5 | c.428T>C p.V143A | Missense Mutation (SNP) | VAF 26/56 reads (46%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.997); catalogued as COSV58637966; called by muse, mutect2, varscan2
- SPATA17 | c.307C>T p.R103* | Nonsense Mutation (SNP) | VAF 10/69 reads (14%) | catalogued as rs780932192, COSV65121993; called by muse, varscan2
- SYNE1 | c.19264C>A p.L6422I (on ENST00000367255 / NM_182961.4; = p.L6351I on NM_033071.3) | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV54928433, COSV55082472; called by muse, mutect2, varscan2
- TFPI2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 33/63 reads (52%) | SIFT tolerated (0.12); PolyPhen benign (0.005); catalogued as COSV55989930, COSV55990186; called by muse, mutect2, varscan2
- TRAPPC9 | c.2930A>G p.E977G | Missense Mutation (SNP) | VAF 15/102 reads (15%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.795); catalogued as rs1563914897; called by muse, mutect2, varscan2
- ZFP42 | c.799C>T p.R267C | Missense Mutation (SNP) | VAF 11/23 reads (48%) | SIFT tolerated (0.05); PolyPhen benign (0.131); catalogued as rs769476367; called by muse, mutect2, varscan2
- ZNF662 | c.109C>T p.R37W | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as rs201335459; called by muse, mutect2, varscan2
- ANO1 | c.2410G>T p.V804L | Missense Mutation (SNP) | VAF 23/35 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- ARHGAP21 | c.3279G>T p.K1093N | Missense Mutation (SNP) | VAF 16/79 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.76); called by muse, mutect2, varscan2
- ASRGL1 | c.641G>A p.G214E | Missense Mutation (SNP) | VAF 15/24 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ATG2B | c.5356_5368del p.V1786Kfs*46 | Frame Shift Del (DEL) | VAF 14/73 reads (19%) | called by mutect2, pindel, varscan2
- BSN | c.3035G>T p.R1012L | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- C1orf127 | c.848_851dup p.Y285Ffs*4 | Frame Shift Ins (INS) | VAF 7/43 reads (16%) | called by mutect2, pindel, varscan2
- CACNA1E | c.5320C>A p.P1774T | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CNTN3 | c.95C>T p.P32L | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CPQ | c.1417T>C p.*473Qext*3 | Nonstop Mutation (SNP) | VAF 40/135 reads (30%) | called by muse, mutect2, varscan2
- DOCK4 | c.3834G>T p.K1278N | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT deleterious (0); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- DPY19L2 | c.2090_2091del p.Y697Cfs*12 | Frame Shift Del (DEL) | VAF 55/207 reads (27%) | called by mutect2, pindel, varscan2
- ELFN2 | c.1976G>A p.G659D | Missense Mutation (SNP) | VAF 9/14 reads (64%) | SIFT tolerated (0.51); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- ELP4 | c.436G>A p.V146I | Missense Mutation (SNP) | VAF 16/55 reads (29%) | SIFT tolerated (0.26); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- GLB1L3 | c.803C>A p.T268N | Missense Mutation (SNP) | VAF 19/34 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- KRR1 | c.33del p.G12Afs*61 | Frame Shift Del (DEL) | VAF 4/38 reads (11%) | called by mutect2, pindel, varscan2
- LANCL1 | c.1174G>A p.A392T | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.861); called by muse, mutect2, varscan2
- LCE3E | c.276C>A p.C92* | Nonsense Mutation (SNP) | VAF 22/93 reads (24%) | called by muse, mutect2, varscan2
- NPNT | c.71+1G>T p.X24_splice | Splice Site (SNP) | VAF 48/90 reads (53%) | called by muse, mutect2, varscan2
- NR1D2 | c.1372G>C p.E458Q | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.779); called by muse, mutect2, varscan2
- NUP153 | c.3216A>C p.K1072N | Missense Mutation (SNP) | VAF 19/50 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- OR13C4 | c.421T>C p.Y141H | Missense Mutation (SNP) | VAF 23/63 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- OSMR | c.2642C>T p.P881L | Missense Mutation (SNP) | VAF 53/73 reads (73%) | SIFT deleterious (0.03); PolyPhen benign (0.162); called by muse, mutect2, varscan2
- PDE3B | c.2536G>T p.D846Y | Missense Mutation (SNP) | VAF 27/77 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R16B | c.692C>T p.T231I | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PQBP1 | c.61G>A p.E21K | Missense Mutation (SNP) | VAF 8/15 reads (53%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.452); called by muse, mutect2, varscan2
- PRKAB1 | c.542G>A p.S181N | Missense Mutation (SNP) | VAF 33/98 reads (34%) | SIFT tolerated (0.17); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- PRMT5 | c.880C>T p.P294S | Missense Mutation (SNP) | VAF 21/100 reads (21%) | SIFT tolerated (0.74); PolyPhen benign (0.288); called by muse, mutect2, varscan2
- PSMD3 | c.1527+2_1527+5dup | Frame Shift Ins (INS) | VAF 11/80 reads (14%) | called by mutect2, pindel, varscan2
- RIF1 | c.6812C>T p.S2271L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.114); called by muse, mutect2, varscan2
- SATB2 | c.1084C>T p.P362S | Missense Mutation (SNP) | VAF 52/104 reads (50%) | SIFT tolerated (1); PolyPhen benign (0.086); called by muse, mutect2, varscan2
- TOMM70 | c.311C>G p.A104G | Missense Mutation (SNP) | VAF 29/105 reads (28%) | SIFT tolerated (0.37); PolyPhen benign (0); called by muse, mutect2, varscan2
- TSNAXIP1 | c.423G>T p.E141D | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.229); called by muse, mutect2, varscan2
- ZBTB12 | c.725_726dup p.L243Tfs*15 | Frame Shift Ins (INS) | VAF 57/155 reads (37%) | called by mutect2, pindel, varscan2
- ZEB2 | c.3550G>C p.E1184Q | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- ZFPM2 | c.1030G>T p.A344S | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- ZNF804B | c.2669A>C p.K890T | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- ADCY8 | c.786C>T p.L262= | Silent (SNP) | VAF 18/78 reads (23%) | catalogued as rs748987496; called by muse, mutect2, varscan2
- AGAP6 | c.1431T>C p.I477= (on ENST00000374056 / NM_001365867.1; = p.I500= on NM_001077665.2) | Silent (SNP) | VAF 56/253 reads (22%) | called by muse, mutect2, varscan2
- AKT3 | c.453G>A p.L151= | Silent (SNP) | VAF 13/66 reads (20%) | catalogued as COSV99795304, COSV99796447; called by muse, mutect2, varscan2
- ATP13A5 | c.114C>T p.V38= | Silent (SNP) | VAF 24/77 reads (31%) | catalogued as rs769286750; called by muse, mutect2, varscan2
- BMP15 | c.678C>A p.S226= | Silent (SNP) | VAF 28/46 reads (61%) | catalogued as COSV53141073, COSV53141172; called by muse, mutect2, varscan2
- CGN | c.2757G>A p.R919= | Silent (SNP) | VAF 5/56 reads (9%) | catalogued as COSV99642901; called by muse, mutect2
- CHFR | c.765C>T p.P255= (on ENST00000432561 / NM_001161345.1; = p.P214= on NM_018223.2) | Silent (SNP) | VAF 46/113 reads (41%) | catalogued as rs1025589682, COSV57174107; called by muse, mutect2, varscan2
- CPNE2 | c.574C>T p.L192= | Silent (SNP) | VAF 5/94 reads (5%) | called by muse, mutect2
- EGFLAM | c.66G>A p.A22= | Silent (SNP) | VAF 8/63 reads (13%) | catalogued as rs772605498; called by muse, mutect2, varscan2
- FAM110B | c.750C>T p.V250= | Silent (SNP) | VAF 12/42 reads (29%) | catalogued as rs759220388, COSV64066845; called by muse, mutect2, varscan2
- FAM47C | c.1428G>A p.P476= | Silent (SNP) | VAF 149/219 reads (68%) | catalogued as rs1439099049, COSV63724050; called by muse, mutect2, varscan2
- FLG2 | c.2643C>T p.Y881= | Silent (SNP) | VAF 64/169 reads (38%) | called by muse, mutect2, varscan2
- FOXG1 | c.624C>T p.Y208= | Silent (SNP) | VAF 30/73 reads (41%) | catalogued as rs267606826, CM100363; called by muse, mutect2, varscan2
- FTCD | c.117C>T p.D39= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as rs751420192; called by muse, mutect2, varscan2
- GJC2 | c.1116G>A p.S372= | Silent (SNP) | VAF 5/9 reads (56%) | called by muse, mutect2, varscan2
- HPSE2 | c.744C>T p.S248= | Silent (SNP) | VAF 25/74 reads (34%) | catalogued as rs763745491, COSV65180216; called by muse, mutect2, varscan2
- MAB21L1 | c.675G>A p.A225= | Silent (SNP) | VAF 18/30 reads (60%) | catalogued as rs1474356089; called by muse, mutect2, varscan2
- NEK5 | c.1296C>T p.A432= | Silent (SNP) | VAF 64/131 reads (49%) | catalogued as rs530160119; called by muse, mutect2, varscan2
- RPRML | c.54C>T p.G18= | Silent (SNP) | VAF 14/29 reads (48%) | catalogued as rs1340635587; called by muse, mutect2
- RTP5 | c.1458C>T p.G486= | Silent (SNP) | VAF 22/102 reads (22%) | catalogued as rs369380323, COSV58319063; called by muse, mutect2, varscan2
- RUSC2 | c.4473C>T p.P1491= | Silent (SNP) | VAF 19/58 reads (33%) | catalogued as rs757539323, COSV100770661; called by muse, mutect2, varscan2
- TAF1C | c.334T>C p.L112= | Silent (SNP) | VAF 14/36 reads (39%) | called by muse, mutect2, varscan2
- TEPSIN | c.201C>T p.H67= | Silent (SNP) | VAF 44/125 reads (35%) | catalogued as rs544653517; called by muse, mutect2, varscan2
- USP10 | c.1101C>T p.P367= | Silent (SNP) | VAF 77/165 reads (47%) | catalogued as rs1250620386, COSV99551379; called by muse, mutect2, varscan2
- VIL1 | c.2172C>T p.S724= | Silent (SNP) | VAF 28/83 reads (34%) | catalogued as rs1460296939; called by muse, mutect2, varscan2
